CCDI case PBBWNR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/9b9fe58f-227d-4c78-9dbc-cfa4fa8df3c6

Demographics
Sex at birth: female; Race: white; Vital status: Dead.

Diagnoses (1)
1. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; Tissue or organ of origin: Gastrointestinal tract, NOS; Age at diagnosis: 19.2 years (7,022 days).

Biospecimens (3 samples)
- Sample 0DJ6K4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJ6KE: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJ6KM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
